Somatic mutation profile of tumor specimen ALCH-B3DV-TTP1-A (aliquot ALCH-B3DV-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3DV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.1 years (26,346 days).
Specimen ALCH-B3DV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c17562a3-568e-41f9-b14b-0ebc19c4dc1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3DV-NB1-A (Blood Derived Normal), aliquot ALCH-B3DV-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1b7a354-67d0-48e5-ab45-25c3342d552b

The open-access MAF lists 229 somatic variants for this specimen: 170 protein-altering or splice-affecting, 39 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 39, Intron 12, Nonsense Mutation 10, Frame Shift Del 6, Splice Region 4, Splice Site 4, 3'UTR 3, RNA 3, Frame Shift Ins 2, 3'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 66/271 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB10 | c.1342C>T p.L448= | Splice Region (SNP) | VAF 121/288 reads (42%) | catalogued as rs60023878; called by muse, mutect2, varscan2
- ADAM20 | c.1321C>G p.L441V | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV56455101; called by muse, mutect2
- ADD1 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757890985, COSV53270879; called by muse, mutect2, varscan2
- ARID2 | c.1840C>T p.Q614* | Nonsense Mutation (SNP) | VAF 44/221 reads (20%) | catalogued as COSV57607839; called by muse, mutect2, varscan2
- C7orf26 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs141231137; called by muse, mutect2, varscan2
- CACNA1E | c.4590C>G p.I1530M | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.398); catalogued as COSV62392343; called by muse, mutect2, varscan2
- CACNA1S | c.4232C>T p.P1411L | Missense Mutation (SNP) | VAF 223/520 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62936978; called by muse, mutect2, varscan2
- CHST10 | c.561T>G p.I187M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV51805612; called by muse, mutect2, varscan2
- CSMD3 | c.10405G>T p.G3469C (on ENST00000297405 / NM_001363185.1; = p.G3300C on NM_052900.3) | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV52240569; called by muse, varscan2
- CSMD3 | c.9269G>T p.G3090V (on ENST00000297405 / NM_001363185.1; = p.G2921V on NM_052900.3) | Missense Mutation (SNP) | VAF 114/451 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99837554; called by muse, mutect2, varscan2
- DGKI | c.1355C>A p.P452H | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55967959; called by muse, mutect2, varscan2
- DNAI2 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs768312326, COSV56761378; ClinVar: uncertain significance; called by muse, mutect2
- ENPP2 | c.658G>T p.G220W | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50015123; called by muse, mutect2
- FAM47A | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.271); catalogued as rs1331001261; called by muse, mutect2, varscan2
- GLRB | c.539C>T p.T180I | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.578); catalogued as COSV100029508, COSV52422617; called by muse, mutect2, varscan2
- GYPC | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 80/374 reads (21%) | SIFT tolerated, low confidence (0.62); PolyPhen probably damaging (0.979); catalogued as rs1558894064, COSV52146425; called by muse, mutect2, varscan2
- HHIP | c.1837C>G p.R613G | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs148372832; called by muse, mutect2, varscan2
- HMGCLL1 | c.257G>T p.R86M | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99232784; called by muse, mutect2, varscan2
- IGHV3-33 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.846); catalogued as rs545619713; called by muse, mutect2
- MAP2K3 | c.114C>A p.P38= (on ENST00000342679 / NM_145109.3; = p.P9= on NM_002756.4) | Splice Region (SNP) | VAF 32/302 reads (11%) | catalogued as COSV57567672; called by muse, mutect2
- MAPK8IP2 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1411619128; called by muse, mutect2, varscan2
- MARCHF1 | c.254G>T p.C85F (on ENST00000274056; = p.C68F on NM_017923.4) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56812493; called by muse, mutect2, varscan2
- MC5R | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as COSV61255786; called by muse, mutect2, varscan2
- MTMR12 | c.800G>T p.W267L | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99373342; called by muse, mutect2, varscan2
- MYO1E | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs765720526; called by muse, mutect2, varscan2
- NEK1 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 26/150 reads (17%) | catalogued as rs368940355; called by muse, mutect2, varscan2
- OLFM1 | c.692C>T p.T231M (on ENST00000371793 / NM_001282611.2; = p.T213M on NM_014279.5) | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as rs1274655533, COSV53276097, COSV53276873; called by muse, mutect2, varscan2
- OR2T3 | c.241G>T p.V81L | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV100613102; called by mutect2, varscan2
- PAX1 | c.880A>C p.N294H | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1568694305; called by muse, mutect2, varscan2
- PCDH15 | c.694del p.I232Sfs*10 | Frame Shift Del (DEL) | VAF 29/151 reads (19%) | catalogued as COSV57363730; called by mutect2, pindel, varscan2
- PCDHA1 | c.1621G>T p.G541C | Missense Mutation (SNP) | VAF 99/294 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100974328; called by muse, mutect2, varscan2
- PCLO | c.6365G>T p.S2122I | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV61638740; called by muse, mutect2, varscan2
- PDE4DIP | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 21/257 reads (8%) | catalogued as rs782470275; called by muse, mutect2
- PDZD7 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.911); catalogued as rs1303874165; called by muse, mutect2, varscan2
- PLAG1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.355); catalogued as rs751939013; called by muse, mutect2, varscan2
- PLEKHH1 | c.546dup p.Y183Lfs*49 | Frame Shift Ins (INS) | VAF 12/69 reads (17%) | catalogued as rs747500686; called by mutect2, pindel, varscan2
- PRKCG | c.962C>A p.S321Y | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV54731993; called by muse, mutect2, varscan2
- PRKD1 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 39/458 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59572410; called by muse, mutect2
- PTPRK | c.3001G>T p.D1001Y (on ENST00000368215 / NM_001291984.2; = p.D1002Y on NM_002844.4) | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100951720; called by muse, mutect2, varscan2
- RYR2 | c.14829G>T p.M4943I | Missense Mutation (SNP) | VAF 105/235 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63705834; called by muse, mutect2, varscan2
- SEC23A | c.1576A>T p.M526L | Missense Mutation (SNP) | VAF 105/420 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs1318773491; called by muse, mutect2, varscan2
- SERPINA9 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 79/319 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV54072692; called by muse, mutect2, varscan2
- SGSM2 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); catalogued as rs1461331644, COSV99280303; called by muse, mutect2, varscan2
- SLC2A10 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs200565780, COSV63713768; called by muse, mutect2, varscan2
- SLC8A1 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.765); catalogued as rs915266590; called by muse, mutect2
- SLITRK4 | c.345C>A p.N115K | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs782576769, COSV62025785, COSV62026257; called by muse, mutect2, varscan2
- SMARCA4 | c.2441C>A p.T814K | Missense Mutation (SNP) | VAF 106/328 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60792950, COSV60795041; called by muse, mutect2, varscan2
- SV2B | c.640G>T p.G214C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305123999; called by muse, mutect2, varscan2
- TMEM39A | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100052614; called by muse, mutect2, varscan2
- TOP2B | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1273825089; called by muse, mutect2, varscan2
- TRIM25 | c.1153+1G>T p.X385_splice | Splice Site (SNP) | VAF 26/157 reads (17%) | catalogued as rs1442989794, COSV57543467; called by muse, mutect2, varscan2
- TRIM75P | c.650G>T p.S217I | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs1173810827; called by muse, mutect2, varscan2
- TSPAN5 | c.117G>T p.W39C | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59878037; called by muse, mutect2
- VPS13A | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs745850156; called by muse, mutect2
- VWA5A | c.1552C>T p.L518F | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as rs771848365; called by muse, mutect2
- WFIKKN2 | c.830C>A p.A277D | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1484728969; called by muse, mutect2, varscan2
- ZMAT4 | c.153G>T p.R51S | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1043468342, COSV52708023; called by muse, mutect2, varscan2
- ZNF107 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as COSV100788596; called by muse, mutect2, varscan2
- ZNF451 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 35/193 reads (18%) | catalogued as COSV100674982; called by muse, mutect2, varscan2
- ZNF512B | c.1178G>A p.S393N | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1300861097; called by muse, mutect2, varscan2
- ZNF592 | c.2575C>T p.Q859* | Nonsense Mutation (SNP) | VAF 15/150 reads (10%) | catalogued as COSV55437382; called by muse, mutect2
- ABHD17C | c.970C>A p.H324N | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- ADAM22 | c.152T>C p.V51A | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ADCY2 | c.3141C>A p.S1047R | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- ADGRD1 | c.810+8G>A | Splice Region (SNP) | VAF 56/173 reads (32%) | called by muse, mutect2, varscan2
- ADGRL3 | c.2111A>T p.Q704L (on ENST00000506720 / NM_001322402.2; = p.Q636L on NM_015236.6) | Missense Mutation (SNP) | VAF 48/312 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- AFP | c.1216C>A p.Q406K | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.217); called by muse, varscan2
- AKAIN1 | c.106C>A p.Q36K | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ANKRD28 | c.2608_2611del p.N870Qfs*13 | Frame Shift Del (DEL) | VAF 13/100 reads (13%) | called by mutect2, pindel, varscan2
- APMAP | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 44/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOBR | c.2411G>A p.G804D (on ENST00000431282; = p.G813D on NM_018690.4) | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- ARFGAP2 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 22/200 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.1141G>T p.D381Y | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ARMC1 | c.115G>T p.G39* | Nonsense Mutation (SNP) | VAF 34/182 reads (19%) | called by muse, mutect2, varscan2
- ASIC5 | c.320C>A p.P107Q | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASRGL1 | c.339del p.H114Ifs*4 | Frame Shift Del (DEL) | VAF 31/123 reads (25%) | called by mutect2, pindel*
- AXDND1 | c.1159del p.E387Rfs*4 | Frame Shift Del (DEL) | VAF 90/281 reads (32%) | called by mutect2, pindel, varscan2
- BAG3 | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BANK1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- BEGAIN | c.1319C>A p.S440* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- BHMG1 | c.632C>A p.P211Q | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- BRSK2 | c.1186C>A p.P396T | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CA13 | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCDC88A | c.4678A>T p.T1560S (on ENST00000436346 / NM_001365480.1; = p.T1532S on NM_018084.5) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.045); called by muse, mutect2
- CCT6A | c.976C>G p.L326V | Missense Mutation (SNP) | VAF 51/299 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- CCT8 | c.184_186del p.K62del | In Frame Del (DEL) | VAF 20/156 reads (13%) | called by mutect2, pindel, varscan2
- CD1E | c.92C>A p.A31E | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CD69 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- CFAP251 | c.2138G>A p.R713K | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CNTN6 | c.1921G>T p.V641L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- COL12A1 | c.6118A>T p.S2040C | Missense Mutation (SNP) | VAF 53/306 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CROCC2 | c.2587C>G p.Q863E | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- CRTAC1 | c.32G>T p.R11M | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CSPP1 | c.2107C>G p.Q703E (on ENST00000676605; = p.Q662E on NM_024790.6) | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.804); called by muse, mutect2
- DCAF12L2 | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDHD2 | c.1417A>T p.S473C | Missense Mutation (SNP) | VAF 67/324 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX53 | c.1165C>T p.Q389* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- DEGS2 | c.566A>G p.N189S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DISP1 | c.3326G>T p.G1109V | Missense Mutation (SNP) | VAF 14/361 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DSCC1 | c.351+2T>A p.X117_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | called by muse, varscan2
- EIF2AK3 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2
- EPHA5 | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 97/462 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA5 | c.1258G>T p.G420C | Missense Mutation (SNP) | VAF 99/463 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EWSR1 | c.1678G>T p.G560C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.756); called by muse, mutect2
- EYA1 | c.395A>T p.Q132L | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAM47A | c.1439C>A p.P480Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); called by muse, varscan2
- FAM47A | c.333G>T p.Q111H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- FAS | c.506-2A>G p.X169_splice | Splice Site (SNP) | VAF 64/380 reads (17%) | called by muse, mutect2, varscan2
- FBXL5 | c.1109A>T p.D370V | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FNBP1L | c.658dup p.E220Gfs*6 | Frame Shift Ins (INS) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- GPC5 | c.1618G>T p.G540C | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- GRIK2 | c.512C>A p.T171N | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- GRIN2A | c.613A>C p.T205P | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- GYPA | c.271+5G>A | Splice Region (SNP) | VAF 12/300 reads (4%) | called by muse, mutect2
- HIC1 | c.614C>G p.S205W (on ENST00000322941 / NM_001098202.1; = p.S186W on NM_006497.4) | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.277); called by muse, mutect2
- IGHV3-30 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 36/465 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2
- KCNJ9 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- KEAP1 | c.511T>C p.C171R | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL42 | c.1331G>T p.C444F | Missense Mutation (SNP) | VAF 98/405 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRT222 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 62/387 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- KRTAP10-5 | c.372del p.S125Pfs*244 | Frame Shift Del (DEL) | VAF 100/397 reads (25%) | called by mutect2, varscan2
- MICAL3 | c.5404G>T p.D1802Y | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.22555G>T p.V7519F | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- NEIL3 | c.463G>C p.V155L | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- NFATC1 | c.425A>T p.E142V | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- NPEPPS | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR1I2 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 69/358 reads (19%) | called by muse, mutect2, varscan2
- NTRK3 | c.1925G>C p.G642A | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- OLFML2B | c.965G>A p.S322N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, varscan2
- OR11L1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 69/543 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- OR2G3 | c.511A>T p.N171Y | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PAK3 | c.1451G>T p.R484M (on ENST00000262836 / NM_001324328.2; = p.R469M on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- PCDH10 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHGA2 | c.1954C>A p.P652T | Missense Mutation (SNP) | VAF 9/247 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PCGF5 | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 56/344 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PFKL | c.683T>G p.L228R | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PKD2 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PLXNA4 | c.498C>A p.S166R | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PRAMEF19 | c.867G>T p.R289S | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- PRMT3 | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 85/298 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRR23C | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- PSMD11 | c.1244A>T p.Y415F | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RYR2 | c.10705G>T p.G3569C | Missense Mutation (SNP) | VAF 113/309 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SALL3 | c.3302T>A p.M1101K | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SATB1 | c.640-1G>C p.X214_splice | Splice Site (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- SBF2 | c.5395C>A p.P1799T | Missense Mutation (SNP) | VAF 54/418 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SEC14L4 | c.203T>A p.L68Q | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SEPSECS | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SERPINB7 | c.382C>G p.R128G | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- SFT2D2 | c.313G>T p.V105L | Missense Mutation (SNP) | VAF 80/443 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SI | c.3395G>C p.G1132A | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SIPA1L2 | c.2311C>A p.P771T | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLC13A3 | c.288del p.L97* | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | called by mutect2, pindel, varscan2
- SLC38A4 | c.1118C>A p.T373K | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SLC5A10 | c.1588G>T p.A530S (on ENST00000395645 / NM_001042450.4; = p.A546S on NM_152351.5) | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SLC8A1 | c.1360G>T p.G454W | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA31A3 | c.2714G>T p.W905L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.514); called by mutect2, varscan2
- SPEG | c.6856C>A p.P2286T | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TAS2R60 | c.134A>C p.E45A | Missense Mutation (SNP) | VAF 62/327 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TFAP2D | c.995C>G p.T332R | Missense Mutation (SNP) | VAF 50/320 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TG | c.1186T>A p.W396R | Missense Mutation (SNP) | VAF 111/458 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMCC2 | c.1921G>T p.A641S | Missense Mutation (SNP) | VAF 146/350 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- UBE2V2 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- USP4 | c.2582G>T p.R861M | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- VPS35L | c.2011C>T p.L671F | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- WSCD2 | c.14G>T p.W5L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX3 | c.6335C>A p.A2112D | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2
- ZNF735 | c.945C>A p.H315Q | Missense Mutation (SNP) | VAF 127/385 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZSCAN20 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACP4 | c.225C>G p.V75= | Silent (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- ADGRL3 | c.2718G>T p.R906= (on ENST00000506720 / NM_001322402.2; = p.R838= on NM_015236.6) | Silent (SNP) | VAF 43/215 reads (20%) | called by muse, mutect2, varscan2
- ARIH2 | c.531G>T p.V177= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- B4GALNT2 | c.888C>A p.A296= | Silent (SNP) | VAF 74/285 reads (26%) | called by muse, mutect2, varscan2
- CPS1 | c.345G>A p.L115= | Silent (SNP) | VAF 86/368 reads (23%) | called by muse, mutect2, varscan2
- CRYGA | c.18C>T p.F6= | Silent (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- CSMD3 | c.3300C>T p.T1100= (on ENST00000297405 / NM_001363185.1; = p.T996= on NM_052900.3) | Silent (SNP) | VAF 61/299 reads (20%) | catalogued as COSV99839669; called by muse, mutect2, varscan2
- CT55 | c.15G>C p.L5= | Silent (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2
- CTNND2 | c.450G>A p.L150= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV58933540; called by muse, mutect2
- E2F7 | c.1069C>A p.R357= | Silent (SNP) | VAF 70/255 reads (27%) | catalogued as COSV59739397; called by muse, mutect2, varscan2
- EFHB | c.882T>C p.Y294= | Silent (SNP) | VAF 32/155 reads (21%) | called by muse, mutect2, varscan2
- EVX1 | c.93G>A p.V31= | Silent (SNP) | VAF 33/161 reads (20%) | called by muse, mutect2, varscan2
- FAM50B | c.705C>A p.L235= | Silent (SNP) | VAF 27/186 reads (15%) | called by muse, mutect2, varscan2
- FASN | c.4614G>T p.R1538= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- FGR | c.909C>T p.F303= | Silent (SNP) | VAF 32/108 reads (30%) | called by muse, mutect2, varscan2
- FNDC3B | c.519A>G p.P173= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs760300359; called by muse, varscan2
- FOXE3 | c.657C>T p.V219= | Silent (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2, varscan2
- GGNBP2 | c.321A>C p.G107= | Silent (SNP) | VAF 122/547 reads (22%) | called by muse, mutect2, varscan2
- GRIA2 | c.1545C>T p.P515= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs1247870346; called by muse, mutect2
- HCN3 | c.492C>A p.I164= | Silent (SNP) | VAF 82/406 reads (20%) | called by muse, mutect2, varscan2
- HP1BP3 | c.405C>T p.S135= | Silent (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- ITGAD | c.1647G>T p.R549= | Silent (SNP) | VAF 32/212 reads (15%) | catalogued as COSV66756810; called by muse, mutect2, varscan2
- JPH3 | c.1875C>A p.P625= | Silent (SNP) | VAF 33/156 reads (21%) | called by muse, mutect2, varscan2
- LMX1A | c.708C>A p.V236= | Silent (SNP) | VAF 70/202 reads (35%) | called by muse, mutect2, varscan2
- MAGEB18 | c.204A>T p.P68= | Silent (SNP) | VAF 47/88 reads (53%) | called by muse, mutect2, varscan2
- OR4A5 | c.207T>A p.A69= | Silent (SNP) | VAF 21/141 reads (15%) | called by muse, mutect2, varscan2
- PFKL | c.684G>T p.L228= | Silent (SNP) | VAF 34/140 reads (24%) | called by muse, mutect2, varscan2
- PI4KA | c.66C>T p.S22= | Silent (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2
- PSMB8 | c.804G>C p.L268= (on ENST00000374882 / NM_148919.4; = p.L264= on NM_004159.5) | Silent (SNP) | VAF 91/412 reads (22%) | called by muse, mutect2, varscan2
- PTPRD | c.5238G>C p.L1746= | Silent (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- RRBP1 | c.1944C>T p.L648= (on ENST00000377813 / NM_001365613.2; = p.L215= on NM_004587.3) | Silent (SNP) | VAF 44/173 reads (25%) | catalogued as rs780858673; called by muse, mutect2, varscan2
- SIRPA | c.1011G>T p.G337= | Silent (SNP) | VAF 54/249 reads (22%) | called by muse, mutect2, varscan2
- SLC17A3 | c.6C>A p.A2= | Silent (SNP) | VAF 84/388 reads (22%) | called by muse, mutect2, varscan2
- SLC6A1 | c.1098G>T p.L366= | Silent (SNP) | VAF 36/163 reads (22%) | catalogued as COSV55118172; called by muse, mutect2, varscan2
- TIAM1 | c.4773C>A p.I1591= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- TMEM121 | c.528G>T p.P176= | Silent (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- UNC80 | c.5400C>A p.S1800= | Silent (SNP) | VAF 59/289 reads (20%) | called by muse, mutect2, varscan2
- WFIKKN2 | c.1548C>T p.P516= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- ZNF445 | c.2061G>A p.G687= | Silent (SNP) | VAF 18/241 reads (7%) | called by muse, mutect2
- AC092718.9 | chr16:81154044 G>A | 3'Flank (SNP) | VAF 23/156 reads (15%) | catalogued as rs1480838951; called by muse, mutect2, varscan2
- AC116351.1 | n.863C>A | RNA (SNP) | VAF 18/72 reads (25%) | catalogued as rs1356918469; called by muse, mutect2
- ADRA1A | c.884-8689T>C | Intron (SNP) | VAF 64/282 reads (23%) | called by muse, mutect2, varscan2
- ARID1B | c.3096+862G>C | Intron (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
- ASH1L | c.5828+4760C>T | Intron (SNP) | VAF 37/330 reads (11%) | catalogued as rs769927341; called by muse, mutect2, varscan2
- BIRC3 | c.953+1227C>T | Intron (SNP) | VAF 21/290 reads (7%) | called by muse, mutect2
- CBX7 | c.179+49G>T | Intron (SNP) | VAF 29/112 reads (26%) | catalogued as rs775710182; called by muse, mutect2, varscan2
- EGFR | c.*7A>G | 3'UTR (SNP) | VAF 26/469 reads (6%) | called by muse, mutect2
- FRMD8P1 | n.607C>A | RNA (SNP) | VAF 64/130 reads (49%) | catalogued as rs764760221; called by muse, mutect2, varscan2
- JPH3 | c.2167-1039G>A | Intron (SNP) | VAF 9/42 reads (21%) | catalogued as rs1468872676; called by muse, mutect2, varscan2
- LINC01553 | n.1202G>A | RNA (SNP) | VAF 8/183 reads (4%) | called by muse, mutect2
- LINC02253 | n.488-13510C>A | Intron (SNP) | VAF 13/179 reads (7%) | called by muse, mutect2
- NAA10 | c.*13C>T | 3'UTR (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2
- NME9 | c.91+370G>T | Intron (SNP) | VAF 32/268 reads (12%) | called by muse, mutect2, varscan2
- NPNT | c.172+14189T>G | Intron (SNP) | VAF 61/320 reads (19%) | called by muse, mutect2, varscan2
- PDS5A | c.*26G>A | 3'UTR (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- PTGS1 | c.94+558G>T | Intron (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- RGS11 | c.318+315G>T | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- STUB1 | chr16:684420 C>A | 3'Flank (SNP) | VAF 34/114 reads (30%) | catalogued as rs1279438004; called by muse, mutect2, varscan2
- TTN | c.34265-3008G>T | Intron (SNP) | VAF 49/299 reads (16%) | called by muse, mutect2, varscan2
